Somatic mutation profile of tumor specimen TARGET-30-PATSDR-01A (aliquot TARGET-30-PATSDR-01A-01D) from TARGET case TARGET-30-PATSDR, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.9 years (680 days).
Specimen TARGET-30-PATSDR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d53ef8d-0659-421a-9d96-45b11d4d0710.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATSDR-10A (Blood Derived Normal), aliquot TARGET-30-PATSDR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7da6c20a-4cc0-4e4f-a522-8753df591137

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPP2R3B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1273147752, COSV66814125; called by muse, mutect2, varscan2
